CCDI case PBBIDF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5a5ba19b-59c6-438d-9360-2c9ef35f7a4c

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,283 days).

Biospecimens (2 samples)
- Sample 0DAEHE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DAEHR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
